TCGA case TCGA-DS-A7WF — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Complex Epithelial Neoplasms; Primary site: Cervix uteri; Tissue source site: Cedars Sinai. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d02ffaa9-0403-4a89-be01-cce35c80dd69

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 41 years; Vital status: Dead; Days to death: 492 days (1.3 years); Cause of death: Cancer Related.

Diagnoses (4)
1. Adenosquamous carcinoma (the primary disease): ICD-O-3 morphology code: 8560/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 41.9 years (15,319 days); Year of diagnosis: 2006; Method of diagnosis: Biopsy; AJCC pathologic T: T1b2; AJCC pathologic N: N0; AJCC pathologic M: MX; FIGO stage: Stage IB2; FIGO staging edition year: 1995; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 23; Lymphatic invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 80 days; Days to treatment end: 397 days (1.1 years); Treatment outcome: Partial Response.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 80 days; Days to treatment end: 387 days (1.1 years); Treatment outcome: Partial Response; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 341 days; Days to treatment end: 397 days (1.1 years); Treatment dose: 3,000 cGy; Treatment outcome: Progressive Disease; Number of fractions: 10; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Brachytherapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Partial Response; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Treatment outcome: Partial Response; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Partial Response; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative.
2. Metastasis of diagnosis 1 (Adenosquamous carcinoma), site: Brain, NOS. Age at diagnosis: 42.8 years (15,640 days); Days to diagnosis: 321 days; Prior treatment: Yes.
3. Metastasis of diagnosis 1 (Adenosquamous carcinoma), site: Lung, NOS. Age at diagnosis: 42.8 years (15,640 days); Days to diagnosis: 321 days; Prior treatment: Yes.
4. Metastasis of diagnosis 1 (Adenosquamous carcinoma), site: Liver. Age at diagnosis: 42.8 years (15,640 days); Days to diagnosis: 321 days; Prior treatment: Yes.

Follow-up (5 entries)
- Day 321 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Brain, NOS; Days to progression: 321 days; Evidence of progression type: Convincing Image Source.
- Day 321 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 321 days; Evidence of progression type: Convincing Image Source.
- Day 321 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 321 days; Evidence of progression type: Convincing Image Source.
- Days to follow up: 492 days (1.3 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Preoperative.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Miscarriage.
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal; Pregnant at diagnosis: No.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used; Hysterectomy type: Radical Hysterectomy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Ectopic Pregnancy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Stillbirth.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Induced Abortion.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Live Birth.
- Timepoint category: Initial Diagnosis; Weight: 63 kg; Height: 160 cm; BMI: 24.6.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 7.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DS-A7WF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 230 mg.
  Slide TCGA-DS-A7WF-01A-01-TSA: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-DS-A7WF-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DS-A7WF-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 1; Pregnancies count miscarriage: 1; Pregnancies count induced abortion: 1; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Total pregnancy count: 3; Tobacco smoking history indicator: 2; Treatment outcome first course: Partial Remission/Response; Submitted tumor site: Cervical; Histologic diagnosis: Adenosquamous; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Lymph nodes examined: Yes; Lymphovascular invasion: Present; Cause of death: Cervical Cancer.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Cause of death: Cervical Cancer; Treatment outcome first course: Partial Remission/Response.
- Radiation treatment 1: Treatment best response: Radiographic Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 492 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 492 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 321 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DS-A7WF-01A-11D-A350-01): tumor purity 0.94, ploidy 2, whole-genome doublings 0.
